Somatic mutation profile of tumor specimen 0DJM95 from CCDI case PBBXEL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 12.6 years (4,590 days).
Specimen 0DJM95: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 420ab6c9-fda6-49ba-9cb8-6c0b92d32eb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJM8L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17ff5d1c-a4ea-4d74-9bcc-cb78f5cdcaf9

The open-access MAF lists 110 somatic variants for this specimen: 59 protein-altering or splice-affecting, 25 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 25, Intron 13, 3'UTR 5, Nonsense Mutation 5, 5'UTR 3, 5'Flank 3, Splice Site 2, 3'Flank 1, Splice Region 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 1374/1868 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CADM4 | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 358/1142 reads (31%) | SIFT tolerated (1); PolyPhen possibly damaging (0.548); catalogued as COSV55928851; called by muse, varscan2
- CCDC22 | c.1346G>T p.R449L | Missense Mutation (SNP) | VAF 483/544 reads (89%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV100873196; called by muse, varscan2
- CD5 | c.1192G>A p.G398S | Missense Mutation (SNP) | VAF 391/1590 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs149639963; called by muse, varscan2
- CSMD1 | c.4684C>T p.R1562W (on ENST00000520002; = p.R1561W on NM_033225.6) | Missense Mutation (SNP) | VAF 386/942 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1412211780; called by muse, varscan2
- CSRNP1 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 329/730 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs372981794; called by muse, varscan2
- GALR2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 480/1326 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as rs1341834484; called by muse, varscan2
- GGT1 | c.249G>C p.M83I | Missense Mutation (SNP) | VAF 434/1634 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.516); catalogued as rs1178111228; called by muse, varscan2
- GPR137C | c.1166G>A p.S389N | Missense Mutation (SNP) | VAF 424/1076 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs757831670; called by muse, varscan2
- HSD17B6 | c.116C>G p.S39W | Missense Mutation (SNP) | VAF 320/1418 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59108682; called by muse, varscan2
- LIPK | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 562/1506 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV101344988; called by muse, varscan2
- LVRN | c.491C>A p.P164Q | Missense Mutation (SNP) | VAF 320/1055 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV63497863; called by muse, varscan2
- MACIR | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 556/1683 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV60634906; called by muse, varscan2
- MKRN3 | c.375G>T p.K125N | Missense Mutation (SNP) | VAF 414/1056 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58809931; called by muse, varscan2
- PALM2AKAP2 | c.1948G>A p.A650T (on ENST00000259318 / NM_001136562.3; = p.A881T on NM_007203.5) | Missense Mutation (SNP) | VAF 86/834 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV52182558; called by muse, varscan2
- PAN3 | c.915C>G p.N305K | Missense Mutation (SNP) | VAF 488/2196 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as COSV66707969; called by muse, varscan2
- SCN8A | c.3529G>T p.E1177* | Nonsense Mutation (SNP) | VAF 394/2308 reads (17%) | catalogued as rs148742419; called by muse, varscan2
- SENP2 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 596/1024 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1180465476; called by muse, varscan2
- TNS1 | c.2756G>T p.R919L | Missense Mutation (SNP) | VAF 342/1091 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs777917136, COSV50715934; called by muse, varscan2
- ZNF716 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 498/1444 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.923); catalogued as rs782211328, COSV101348444; called by muse, varscan2
- ACTN3 | c.1459A>T p.N487Y | Missense Mutation (SNP) | VAF 328/1269 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, varscan2
- ADARB1 | c.100G>T p.G34W | Missense Mutation (SNP) | VAF 550/1314 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); called by muse, varscan2
- AK6 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 526/1966 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, varscan2
- AKAP10 | c.1671A>G p.I557M | Missense Mutation (SNP) | VAF 146/1307 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, varscan2
- AL358113.1 | c.3898T>G p.S1300A | Missense Mutation (SNP) | VAF 619/1220 reads (51%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.03); called by muse, varscan2
- AVL9 | c.61G>C p.V21L | Missense Mutation (SNP) | VAF 272/705 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- CCSER1 | c.2156A>C p.E719A | Missense Mutation (SNP) | VAF 416/1115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CEP78 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 476/1112 reads (43%) | called by muse, varscan2
- CRTAP | c.777C>A p.F259L | Missense Mutation (SNP) | VAF 452/1111 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, varscan2
- CSF2RA | c.459C>G p.Y153* | Nonsense Mutation (SNP) | VAF 426/908 reads (47%) | called by muse, varscan2
- CXorf58 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 694/792 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.509); called by muse, varscan2
- DNAH9 | c.2000G>T p.C667F | Missense Mutation (SNP) | VAF 368/1422 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.296); called by muse, varscan2
- EFCAB3 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 380/1344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- ELAPOR1 | c.2324T>C p.L775P | Missense Mutation (SNP) | VAF 329/794 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, varscan2
- FRMD6 | c.306A>C p.Q102H (on ENST00000344768 / NM_001267046.2; = p.Q94H on NM_152330.4) | Missense Mutation (SNP) | VAF 291/726 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, varscan2
- HSD17B12 | c.173G>T p.S58I | Missense Mutation (SNP) | VAF 506/1880 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, varscan2
- KCNV1 | c.209T>C p.V70A | Missense Mutation (SNP) | VAF 237/692 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, varscan2
- MGA | c.6235G>T p.E2079* (on ENST00000219905 / NM_001164273.1; = p.E1870* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 625/1464 reads (43%) | called by muse, varscan2
- MRPL28 | c.705C>G p.I235M | Missense Mutation (SNP) | VAF 186/700 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, varscan2
- MYH15 | c.1036-1G>A p.X346_splice | Splice Site (SNP) | VAF 470/1195 reads (39%) | called by muse, varscan2
- NCOA6 | c.1613C>A p.A538E | Missense Mutation (SNP) | VAF 886/3610 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.054); called by muse, varscan2
- NISCH | c.3131A>T p.Q1044L | Missense Mutation (SNP) | VAF 213/475 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.084); called by muse, varscan2
- PAPPA2 | c.4322A>T p.Q1441L | Missense Mutation (SNP) | VAF 1110/1996 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, varscan2
- PLA2G4A | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 588/1052 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- PLPPR5 | c.335T>A p.I112K | Missense Mutation (SNP) | VAF 642/1451 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, varscan2
- POM121L12 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 582/1526 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, varscan2
- PPFIBP1 | c.1179C>A p.N393K (on ENST00000318304 / NM_177444.3; = p.N376K on NM_003622.4) | Missense Mutation (SNP) | VAF 438/1874 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, varscan2
- RPL10L | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 181/1704 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, varscan2
- RTN3 | c.2309C>A p.S770Y (on ENST00000377819 / NM_001265589.2; = p.S751Y on NM_201428.3) | Missense Mutation (SNP) | VAF 588/2183 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.355); called by muse, varscan2
- SBF1 | c.2766G>T p.L922F | Missense Mutation (SNP) | VAF 278/992 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- SEC24C | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 498/1263 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.459); called by muse, varscan2
- SLC40A1 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 548/1454 reads (38%) | called by muse, varscan2
- SPATA31A1 | c.4043G>T p.*1348Lext*9 | Nonstop Mutation (SNP) | VAF 178/1546 reads (12%) | called by muse, varscan2
- STX11 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 190/738 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, varscan2
- TMEFF2 | c.534C>A p.V178= | Splice Region (SNP) | VAF 508/1186 reads (43%) | called by muse, varscan2
- TRPC5OS | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 651/743 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, varscan2
- UNC13C | c.6206C>A p.A2069D | Missense Mutation (SNP) | VAF 286/750 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); called by muse, varscan2
- VASP | c.479-1G>T p.X160_splice | Splice Site (SNP) | VAF 68/289 reads (24%) | called by muse, varscan2
- ZNF264 | c.775T>A p.Y259N | Missense Mutation (SNP) | VAF 420/1454 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ABCC9 | c.2793T>G p.T931= | Silent (SNP) | VAF 564/2600 reads (22%) | called by muse, varscan2
- CCN1 | c.531C>T p.G177= | Silent (SNP) | VAF 564/1512 reads (37%) | called by muse, varscan2
- CLUL1 | c.100C>T p.L34= | Silent (SNP) | VAF 300/1386 reads (22%) | catalogued as COSV58111245; called by muse, varscan2
- CNTNAP1 | c.2161C>A p.R721= | Silent (SNP) | VAF 588/1758 reads (33%) | catalogued as rs199522414; called by muse, varscan2
- GANAB | c.1398C>A p.I466= | Silent (SNP) | VAF 438/1055 reads (42%) | called by muse, varscan2
- HEPH | c.498C>A p.T166= (on ENST00000343002; = p.T220= on NM_138737.5) | Silent (SNP) | VAF 451/522 reads (86%) | called by muse, varscan2
- HOXB2 | c.402A>G p.G134= | Silent (SNP) | VAF 72/599 reads (12%) | catalogued as rs201525000; called by muse, varscan2
- ITGA7 | c.3345C>T p.P1115= (on ENST00000555728; = p.P1071= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 461/1810 reads (25%) | catalogued as rs559955065; called by muse, varscan2
- KCNN4 | c.276G>A p.G92= | Silent (SNP) | VAF 194/748 reads (26%) | catalogued as rs1337896495; called by muse, varscan2
- KLRC1 | c.456C>A p.S152= | Silent (SNP) | VAF 625/2960 reads (21%) | called by muse, varscan2
- LDLR | c.63T>C p.T21= | Silent (SNP) | VAF 270/963 reads (28%) | called by muse, varscan2
- MAPK8IP2 | c.1467C>A p.P489= | Silent (SNP) | VAF 388/1188 reads (33%) | called by muse, varscan2
- MED12 | c.5982G>C p.R1994= | Silent (SNP) | VAF 734/828 reads (89%) | called by muse, varscan2
- NLGN2 | c.261T>G p.P87= | Silent (SNP) | VAF 382/1155 reads (33%) | called by muse, varscan2
- NME7 | c.1029A>G p.A343= | Silent (SNP) | VAF 274/1949 reads (14%) | called by muse, varscan2
- OR5T1 | c.156A>T p.I52= | Silent (SNP) | VAF 514/1602 reads (32%) | called by muse, varscan2
- PCDHB7 | c.825G>T p.G275= | Silent (SNP) | VAF 510/1780 reads (29%) | called by muse, varscan2
- PHF2 | c.3168C>G p.S1056= | Silent (SNP) | VAF 68/644 reads (11%) | catalogued as COSV63680987; called by muse, varscan2
- PLEKHA6 | c.930G>A p.Q310= | Silent (SNP) | VAF 903/1496 reads (60%) | called by muse, varscan2
- RHBDL2 | c.606G>T p.L202= | Silent (SNP) | VAF 118/946 reads (12%) | called by muse, varscan2
- SOX21 | c.67C>A p.R23= | Silent (SNP) | VAF 382/1675 reads (23%) | called by muse, varscan2
- TNRC6B | c.1242T>A p.T414= | Silent (SNP) | VAF 460/1639 reads (28%) | called by muse, varscan2
- TRPS1 | c.2175C>T p.N725= (on ENST00000220888 / NM_001330599.2; = p.N738= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 1078/2038 reads (53%) | catalogued as rs761205610, COSV55266594; called by muse, varscan2
- ZMYM2 | c.3073T>C p.L1025= | Silent (SNP) | VAF 558/2359 reads (24%) | called by muse, varscan2
- ZNF716 | c.318A>C p.S106= | Silent (SNP) | VAF 498/1440 reads (35%) | called by muse, varscan2
- ASPSCR1 | c.1476-10C>A | Intron (SNP) | VAF 539/1609 reads (33%) | called by muse, varscan2
- B4GALT4 | c.-36A>C | 5'UTR (SNP) | VAF 326/1296 reads (25%) | called by muse, varscan2
- DCDC1 | c.4104+94C>A | Intron (SNP) | VAF 94/302 reads (31%) | called by muse, varscan2
- DCLRE1C | c.973-56C>A | Intron (SNP) | VAF 110/282 reads (39%) | called by muse, varscan2
- ERGIC1 | c.642+55A>C | Intron (SNP) | VAF 145/484 reads (30%) | called by muse, varscan2
- FAM205C | chr9:34895730 A>G | 5'Flank (SNP) | VAF 240/588 reads (41%) | called by muse, varscan2
- LILRB3 | chr19:54223052 G>T | 5'Flank (SNP) | VAF 129/916 reads (14%) | called by muse, varscan2
- MUC19 | n.8934C>T | RNA (SNP) | VAF 306/1342 reads (23%) | called by muse, varscan2
- NEB | c.11601+1195G>T | Intron (SNP) | VAF 432/3072 reads (14%) | called by muse, varscan2
- NEK5 | c.*30A>G | 3'UTR (SNP) | VAF 301/1349 reads (22%) | called by muse, varscan2
- OLFML2B | c.1475-70A>G | Intron (SNP) | VAF 84/425 reads (20%) | called by muse, varscan2
- PCDHGA6 | c.2424+109G>T | Intron (SNP) | VAF 104/362 reads (29%) | called by muse, varscan2
- PDILT | c.*22dup | 3'UTR (INS) | VAF 161/495 reads (33%) | catalogued as rs770563345; called by pindel, varscan2
- PLA2G4C | c.-32-9C>A | Intron (SNP) | VAF 315/1104 reads (29%) | called by muse, varscan2
- POLR2M | c.-90A>T | 5'UTR (SNP) | VAF 146/354 reads (41%) | called by muse, varscan2
- PRC1 | c.1461+80G>T | Intron (SNP) | VAF 332/482 reads (69%) | called by muse, varscan2
- PYCR3 | chr8:143609611 C>A | 5'Flank (SNP) | VAF 89/171 reads (52%) | called by muse, varscan2
- REPS2 | c.546+65G>C | Intron (SNP) | VAF 266/300 reads (89%) | catalogued as rs183795851, COSV100380861; called by muse, varscan2
- SARS1 | c.*60G>T | 3'UTR (SNP) | VAF 278/602 reads (46%) | called by muse, varscan2
- SLAMF8 | chr1:159840936 G>T | 3'Flank (SNP) | VAF 97/328 reads (30%) | called by muse, varscan2
- STARD10 | c.578-63C>A | Intron (SNP) | VAF 134/466 reads (29%) | called by muse, varscan2
- TARBP2 | c.423-90G>T | Intron (SNP) | VAF 30/168 reads (18%) | called by muse, varscan2
- TARBP2 | c.423-89A>T | Intron (SNP) | VAF 31/172 reads (18%) | called by muse, varscan2
- TPTE | c.*33T>C | 3'UTR (SNP) | VAF 200/1912 reads (10%) | catalogued as rs769137753; called by muse, varscan2
- TRAM2 | c.-2C>A | 5'UTR (SNP) | VAF 242/870 reads (28%) | called by muse, varscan2
- ZSCAN9 | c.*78T>G | 3'UTR (SNP) | VAF 97/361 reads (27%) | called by muse, varscan2
